Gene-level copy-number profile of tumor specimen HCM-BROD-0689-C71-02A from HCMI case HCM-BROD-0689-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.1 years (23,030 days).
Specimen HCM-BROD-0689-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fcafdb55-d115-4c17-9e8d-8e0494e4a3c5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0689-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/dea441d1-e9fe-488f-8534-ff3acba28b4b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 1,300; copy number 2: 43,857; copy number 3: 7,567; copy number 4: 5,595; copy number 5: 48; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr1:248,573,801–248,635,091, 5 genes: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11.
- chr5:795,606–850,986, 2 genes (within-gene range 0–2): ZDHHC11, SPCS2P3.
- chr5:17,601,882–17,625,959, 6 genes: AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21.
- chr5:124,059,794–124,438,625, 3 genes (within-gene range 0–2): LINC01170, HMGB1P29, AC016556.1.
- chr11:79,604,967–79,612,300, 1 gene: AP001978.1.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.
- chr13:48,303,744–48,599,436, 6 genes (within-gene range 0–2): RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.
- chr14:100,109,419–100,159,645, 3 genes (within-gene range 0–2): MIR151B, MIR342, DEGS2.
- chr17:18,432,051–18,494,945, 6 genes: KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene, copy number 5 (within-gene range 2–9): RSRP1.
- chr1:25,266,102–25,337,465, 4 genes, copy number 5 (within-gene range 5–9): AL031432.2, RHD, SDHDP6, AL928711.1.
- chr5:180,967,189–180,970,762, 2 genes, copy number 6: AC091874.2, AC091874.1.
- chr9:61,190,003–61,642,494, 10 genes, copy number 5: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 1,300. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
